Somatic mutation profile of tumor specimen 0DBNCT from CCDI case PBBKBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,759 days).
Specimen 0DBNCT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b04b361-553c-435a-bde8-e3ae60b17e51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBNBL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e54f2bd-e5f0-4923-885f-e34d9157f712

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Splice Region 1, Splice Site 1, 5'UTR 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 258/860 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIF21B | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 469/1013 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs778836144, COSV59756104; called by muse, mutect2, varscan2
- SBK2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1239093167; called by muse, mutect2, varscan2
- ANKRD10 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1175 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HEATR1 | c.1304+1G>T p.X435_splice | Splice Site (SNP) | VAF 119/715 reads (17%) | called by muse, mutect2, varscan2
- PLA2G5 | c.291C>T p.C97= | Splice Region (SNP) | VAF 180/516 reads (35%) | called by muse, mutect2
- TMEM30B | c.832C>A p.L278M | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADAM22 | c.813C>T p.N271= | Silent (SNP) | VAF 64/1508 reads (4%) | catalogued as COSV55984914; called by muse, mutect2
- MYH9 | c.2685G>T p.L895= | Silent (SNP) | VAF 105/602 reads (17%) | called by muse, mutect2, varscan2
- PLIN2 | c.573C>T p.L191= | Silent (SNP) | VAF 39/341 reads (11%) | catalogued as rs1489982388, COSV99439182; called by muse, mutect2, varscan2
- AKAP13 | c.*66_*72dup | 3'UTR (INS) | VAF 83/226 reads (37%) | called by mutect2, varscan2
- MTDHP2 | n.676A>G | RNA (SNP) | VAF 85/181 reads (47%) | called by muse, mutect2, varscan2
- MYOF | c.-88C>G | 5'UTR (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
